Gene-level copy-number profile of tumor specimen TCGA-AR-A1AW-01A from TCGA case TCGA-AR-A1AW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.3 years (23,855 days).
Specimen TCGA-AR-A1AW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4fe5e02e-c89b-445d-8b84-8db10e210c86.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/991551b2-26a3-40da-9baf-f391b79c8bd6

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 32,474; copy number 2: 17,848; copy number 3: 6,468; copy number 4: 1,145; copy number 5: 1,458; copy number 6: 101; copy number 7: 186; copy number 8: 66; copy number 20: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AW-01A-21D-A12N-01): tumor purity 0.26, ploidy 2.15, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:93,130,056–94,495,404, 24 genes: SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, AC002074.2, COL1A2, RNU6-1328P.
- chr18:80,034,346–80,097,088, 1 gene (within-gene range 0–3): AC090360.1.
- chr18:80,046,900–80,247,514, 7 genes (within-gene range 0–3): RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr21:26,835,755–29,073,797, 30 genes: ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 9,432 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–2,391,707, 152 genes, copy number 3 (broad region; genes not listed).
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 3 (broad region; genes not listed).
- chr8:43,246,755–145,066,685, 1,555 genes, copy number 5–20 (broad region; genes not listed).
- chr10:37,337,415–133,761,125, 1,696 genes, copy number 3 (broad region; genes not listed).
- chr11:128,965,060–130,916,479, 38 genes, copy number 4: ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1.
- chr11:132,414,977–133,532,519, 1 gene, copy number 4 (within-gene range 2–4): OPCML.
- chr11:133,064,697–134,265,855, 20 genes, copy number 4: AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8.
- chr18:20,946,906–22,419,294, 40 genes, copy number 3: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.
- chr18:60,628,963–60,902,726, 1 gene, copy number 4 (within-gene range 2–4): AC113137.1.
- chr18:60,794,613–78,544,188, 227 genes, copy number 3–5 (broad region; genes not listed).
- chr18:79,069,285–80,033,949, 29 genes, copy number 3 (within-gene range 1–3): ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A.
- chr18:80,034,389–80,050,651, 1 gene, copy number 3: RBFA.
- chr19:3,314,403–58,605,223, 2,779 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr20:87,250–2,470,853, 74 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr20:2,536,607–13,996,443, 205 genes, copy number 3–6 (within-gene range 1–6) (broad region; genes not listed).
- chr20:14,003,508–14,929,528, 10 genes, copy number 5 (within-gene range 2–5): RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1.

Autosomal genes at a single copy (total copy number 1): 30,053. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
